Gene-level copy-number profile of tumor specimen HTMCP-01-06-00242-01A from CGCI case HTMCP-01-06-00242, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS.
Specimen HTMCP-01-06-00242-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 43ba61ee-1736-493c-826c-46706edb6778.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00242-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/0584e287-652a-47ac-a0c4-b6ea0550a770

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 619; copy number 2: 41,675; copy number 3: 14,327; copy number 4: 1,735; copy number 5: 2; copy number 6: 12.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,860,568–88,992,931, 14 genes (within-gene range 0–1): IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8.
- chr2:89,027,171–89,027,731, 1 gene (within-gene range 0–1): IGKV3-11.
- chr14:105,639,559–105,644,790, 1 gene (within-gene range 0–1): IGHG2.
- chr14:105,647,924–105,673,314, 3 genes (within-gene range 0–1): COPDA1, IGHGP, ELK2AP.
- chr14:105,721,794–105,722,527, 1 gene (within-gene range 0–1): IGHEP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,249,572, 1 gene, copy number 6: TRGC2.
- chr7:38,257,879–38,330,935, 11 genes, copy number 6 (within-gene range 3–6): TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, AC006033.2, TRGV8.
- chr18:15,307,663–15,330,282, 2 genes, copy number 5: AP005901.1, RNU6-721P.

Autosomal genes at a single copy (total copy number 1): 619. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
